Somatic mutation profile of tumor specimen MMRF_2756_1_BM_CD138pos (aliquot MMRF_2756_1_BM_CD138pos_T1_KHS5U_L15091) from MMRF case MMRF_2756, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2756_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cdb96ad-a755-475c-bb28-5c02deb96681.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2756_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2756_1_PB_WBC_C2_KHS5U_L15092; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d273df1b-d8ef-492e-bc7f-8507ae513adb

The open-access MAF lists 101 somatic variants for this specimen: 49 protein-altering or splice-affecting, 10 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 23, Silent 10, Intron 9, RNA 6, Nonsense Mutation 3, Splice Region 3, 5'UTR 2, Frame Shift Del 2, 3'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 147/351 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, mutect2, varscan2
- ADAMTS2 | c.3013G>A p.A1005T | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs757793067, COSV52371239; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.764); catalogued as COSV57516793; called by muse, mutect2, varscan2
- FKBP9 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.788); catalogued as rs748874793; called by muse, mutect2, varscan2
- IGHJ6 | c.15C>G p.Y5* | Nonsense Mutation (SNP) | VAF 47/82 reads (57%) | catalogued as rs1156371941; called by muse, varscan2
- IGHV2-70 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs372813642; called by muse, varscan2
- IGHV2-70 | c.230A>C p.D77A | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs546960655; called by muse, varscan2
- IGLV3-1 | c.61T>A p.Y21N | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as rs372924773; called by muse, varscan2
- IGLV3-1 | c.148T>G p.Y50D | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as rs368495152; called by muse, varscan2
- IGLV3-1 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs374018767; called by muse, varscan2
- LRFN2 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as rs781110254, COSV100599697, COSV57830158; called by muse, mutect2, varscan2
- PLA2G6 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs780784951; called by muse, mutect2, varscan2
- POMT2 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.101); catalogued as COSV55073972; called by muse, mutect2, varscan2
- PTPN5 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 106/449 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1037962955, COSV62125787; called by muse, mutect2, varscan2
- ROBO2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 81/288 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59907550; called by muse, mutect2, varscan2
- SENP5 | c.1691A>G p.Y564C | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1475526413, COSV60210543; called by muse, mutect2, varscan2
- SIGLEC11 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs747895469; called by muse, mutect2, varscan2
- TTC16 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs768857855; called by muse, mutect2, varscan2
- ZNF112 | c.2063C>T p.T688M (on ENST00000337401 / NM_001083335.2; = p.T682M on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/250 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs139015866; called by muse, mutect2, varscan2
- ADAM29 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ANKFN1 | c.3475_3493del p.G1159Ifs*50 (on ENST00000653862; = p.G1012Ifs*50 on NM_001365758.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/276 reads (11%) | called by mutect2, pindel
- ATP10D | c.2368C>G p.Q790E | Missense Mutation (SNP) | VAF 121/254 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH5 | c.618A>G p.G206= | Splice Region (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- CES5A | c.1049T>G p.L350R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP2R1 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 61/239 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DGKQ | c.1744_1745del p.L582Afs*99 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by mutect2, pindel, varscan2
- DNAH12 | c.3633C>G p.C1211W (on ENST00000351747; = p.C1234W on NM_001366028.2) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, varscan2
- FMO2 | c.1010T>A p.F337Y | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXP1 | c.1664T>C p.L555P | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- FSIP2 | c.8035A>C p.K2679Q | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- FSIP2 | c.14410C>T p.Q4804* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- GALP | c.155T>C p.M52T | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- GBE1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GFPT2 | c.280G>C p.A94P | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHJ6 | c.47T>A p.V16D | Missense Mutation (SNP) | VAF 28/66 reads (42%) | PolyPhen probably damaging (0.974); called by muse, varscan2
- IGLV3-1 | c.236G>C p.R79P | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- LHX8 | c.352A>C p.K118Q | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MAGI3 | c.4165A>C p.T1389P | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP9 | c.482-7T>A | Splice Region (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- PALD1 | c.1122+1G>C p.X374_splice | Splice Site (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- PALLD | c.1740A>C p.K580N | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTPRCAP | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 132/306 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- SCFD1 | c.120A>C p.E40D | Missense Mutation (SNP) | VAF 115/297 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC6A15 | c.1924T>A p.F642I | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SORCS2 | c.2269T>C p.S757P | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- TSLP | c.47A>T p.K16I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- TYK2 | c.1789C>T p.Q597* | Nonsense Mutation (SNP) | VAF 39/135 reads (29%) | called by muse, mutect2, varscan2
- VWFP1 | n.283G>T | Splice Region (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- ZP3 | c.1066G>C p.E356Q (on ENST00000394857 / NM_001110354.2; = p.E305Q on NM_007155.6) | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ALDH3A1 | c.198C>T p.Y66= | Silent (SNP) | VAF 88/218 reads (40%) | catalogued as rs1358833091, COSV56734540, COSV56734797; called by muse, varscan2
- BOLA1 | c.48C>T p.R16= | Silent (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2, varscan2
- CALN1 | c.9G>A p.L3= | Silent (SNP) | VAF 65/129 reads (50%) | called by muse, mutect2, varscan2
- FAT3 | c.10062C>T p.A3354= | Silent (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- HMCN1 | c.5793T>A p.T1931= | Silent (SNP) | VAF 35/276 reads (13%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.189G>A p.G63= | Silent (SNP) | VAF 86/182 reads (47%) | catalogued as rs112642180; called by muse, varscan2
- OTUD7A | c.1434C>G p.A478= (on ENST00000307050 / NM_001382637.1; = p.A471= on NM_130901.3) | Silent (SNP) | VAF 127/289 reads (44%) | called by muse, mutect2, varscan2
- PARD3B | c.1554C>T p.S518= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV62525153; called by muse, mutect2, varscan2
- RASGRF2 | c.2526G>A p.A842= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as rs755800361, COSV54127393; called by muse, mutect2, varscan2
- SLIT3 | c.1104C>T p.T368= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs373058615; called by muse, mutect2, varscan2
- AADACL3 | c.*1015T>G | 3'UTR (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- ABCA13 | c.*182T>G | 3'UTR (SNP) | VAF 58/137 reads (42%) | called by muse, mutect2, varscan2
- AC106818.1 | n.447G>A | RNA (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- AC142384.1 | n.1413G>C | RNA (SNP) | VAF 65/185 reads (35%) | called by muse, mutect2, varscan2
- ANK2 | c.*743A>C | 3'UTR (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- ARHGAP5 | c.*2061C>T | 3'UTR (SNP) | VAF 17/104 reads (16%) | catalogued as rs953387825; called by muse, varscan2
- B3GALNT1 | c.*1686A>G | 3'UTR (SNP) | VAF 84/153 reads (55%) | catalogued as rs1175029389; called by muse, mutect2, varscan2
- C19orf44 | c.*550G>A | 3'UTR (SNP) | VAF 13/35 reads (37%) | catalogued as rs1156871461; called by muse, mutect2, varscan2
- CCT7 | c.-71A>G | 5'UTR (SNP) | VAF 77/198 reads (39%) | catalogued as rs1367001696, COSV99240137; called by muse, mutect2, varscan2
- CDH19 | c.*769A>C | 3'UTR (SNP) | VAF 89/135 reads (66%) | called by muse, mutect2, varscan2
- CPNE9 | c.1476+163A>G | Intron (SNP) | VAF 79/356 reads (22%) | called by muse, mutect2, varscan2
- DHRS3 | c.339+126C>A | Intron (SNP) | VAF 19/40 reads (48%) | catalogued as rs780350885; called by muse, mutect2, varscan2
- ETS2 | c.-326G>T | 5'UTR (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- FAM169B | n.1986C>G | RNA (SNP) | VAF 31/164 reads (19%) | catalogued as rs765599644; called by muse, mutect2, varscan2
- HNRNPK | c.1361+378C>T | Intron (SNP) | VAF 69/204 reads (34%) | called by muse, mutect2, varscan2
- LL22NC03-63E9.3 | n.1554A>T | RNA (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- MIR1270 | chr19:20397503 G>A | 3'Flank (SNP) | VAF 24/207 reads (12%) | called by muse, mutect2, varscan2
- MRGPRX10P | n.423G>A | RNA (SNP) | VAF 17/75 reads (23%) | catalogued as rs1018310766; called by muse, mutect2, varscan2
- MRGPRX2 | c.*7A>G | 3'UTR (SNP) | VAF 202/459 reads (44%) | called by muse, mutect2, varscan2
- NAA50 | c.8+197G>A | Intron (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2
- NOS1 | c.*2295G>T | 3'UTR (SNP) | VAF 29/64 reads (45%) | catalogued as rs941232371; called by muse, mutect2, varscan2
- PATE1 | c.53-8del | Intron (DEL) | VAF 87/218 reads (40%) | catalogued as rs745805577; called by mutect2, varscan2
- PCDH17 | c.*3756A>C | 3'UTR (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- PCMTD1 | c.*2285G>A | 3'UTR (SNP) | VAF 9/122 reads (7%) | catalogued as rs1476169250; called by muse, mutect2
- PDCD6IPP2 | n.143A>C | RNA (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- PIK3C2A | c.*2121A>C | 3'UTR (SNP) | VAF 52/112 reads (46%) | called by muse, mutect2, varscan2
- PLCXD1 | c.*3694C>T | 3'UTR (SNP) | VAF 138/354 reads (39%) | catalogued as rs763006160; called by muse, mutect2, varscan2
- POLR1F | c.*944C>T | 3'UTR (SNP) | VAF 19/77 reads (25%) | catalogued as rs959147419; called by muse, mutect2, varscan2
- PRDM16 | c.*2386T>C | 3'UTR (SNP) | VAF 18/134 reads (13%) | called by mutect2, varscan2
- RHPN1 | c.*732T>C | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- RMDN1 | c.*1578A>T | 3'UTR (SNP) | VAF 17/203 reads (8%) | called by muse, mutect2
- RPAP1 | c.331-107C>G | Intron (SNP) | VAF 21/31 reads (68%) | called by muse, mutect2, varscan2
- SIAE | c.*3178T>C | 3'UTR (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- SLC5A12 | c.*793A>C | 3'UTR (SNP) | VAF 58/123 reads (47%) | catalogued as rs771792272; called by muse, mutect2
- SNX5 | c.1079-188del | Intron (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- STAC2 | c.*1706G>A | 3'UTR (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- STX17 | c.*523A>G | 3'UTR (SNP) | VAF 34/102 reads (33%) | catalogued as rs552685871; called by muse, mutect2, varscan2
- TAS2R13 | c.*81A>G | 3'UTR (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- TMED4 | c.*1147G>A | 3'UTR (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- TMEM18 | c.57+621C>T | Intron (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- VAX1 | chr10:117130656 T>C | 3'Flank (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- XRCC4 | c.893+88C>T | Intron (SNP) | VAF 9/27 reads (33%) | catalogued as rs1037293511; called by muse, mutect2, varscan2
